Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A2LZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A2LZ-01A (Primary Tumor).

Name: _____
Address: _____

arg. Path. No.: _____
DOB: _____ (Age: _____)
Sex/Race: _____
Service: _____
Date Received: _____
Patient type: _____

Case is (-/circle):		

1CD-0-3

Carcinoma, squamous cell 8070/3
Site: Cervix NOS 053.9 /w 8/18/11

DIAGNOSIS

UTERUS, CERVIX, BIOPSY
- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED
(SEE DESCRIPTION)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis), and that I have reviewed and approved this report.

_____, M.D.

HISTORY

The patient is a _____ year old woman who underwent cervical biopsy.

GROSS

Submitted by Dr. _____ For review is one slide labeled _____ accompanied by a corresponding pathology report. material originated from _____

Source: NCI Genomic Data Commons file d442238e-c694-4b4c-9b24-5907327da58a (TCGA-C5-A2LZ.EF2D354D-F959-45B3-AA5C-170E00AF3F45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).